Somatic mutation profile of tumor specimen ER-B0GF-TTM1-A (aliquot ER-B0GF-TTM1-A-1-0-D-A699-35) from EXCEPTIONAL_RESPONDERS case ER-B0GF, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Tissue or organ of origin: Breast, NOS.
Specimen ER-B0GF-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b714d8da-5709-4104-8eb6-03ba111066db.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-B0GF-NT1-A (Solid Tissue Normal), aliquot ER-B0GF-NT1-A-1-0-D-A699-35; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0586a8c-388c-410e-96c2-de192a62cc66

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, In Frame Del 1, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 257/911 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 136/233 reads (58%) | hotspot (GDC flag); catalogued as rs1567555445, CS951538, COSV52663569, COSV52668477, COSV52702628; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ARID1B | c.2521T>G p.S841A | Missense Mutation (SNP) | VAF 118/772 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- FAT3 | c.9411C>A p.N3137K | Missense Mutation (SNP) | VAF 200/588 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FLT1 | c.1903G>C p.A635P | Missense Mutation (SNP) | VAF 138/937 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ROS1 | c.5487_5534del p.R1829_I1844del | In Frame Del (DEL) | VAF 84/871 reads (10%) | called by mutect2, pindel
- ATM | c.7044G>A p.T2348= | Silent (SNP) | VAF 270/743 reads (36%) | catalogued as rs140104789; ClinVar: conflicting interpretations of pathogenicity / benign / likely benign; called by muse, mutect2, varscan2
